Gene-level copy-number profile of tumor specimen TCGA-24-1852-01A from TCGA case TCGA-24-1852, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.8 years (20,390 days).
Specimen TCGA-24-1852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5e6dcf92-01c3-4eb2-8c8a-5bbeda37fc37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1852-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c91df12a-b109-404a-a1ad-55eae9c5e42a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 113; copy number 2: 8,033; copy number 3: 15,694; copy number 4: 16,501; copy number 5: 13,799; copy number 6: 2,071; copy number 7: 1,551; copy number 8: 601; copy number 9: 540; copy number 10: 162; copy number 11: 125; copy number 12: 203; copy number 13: 21; copy number 14: 75; copy number 19: 64; copy number 21: 38; copy number 23: 169; copy number 24: 47; copy number 31: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1852-01): tumor purity 0.84, ploidy 4.12, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,450 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,653,560–111,768,000, 46 genes, copy number 10: AL365361.1, KCNA3, Y_RNA, NRBF2P3, OR11I1P, CD53, AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54, DRAM2, CEPT1, AL355816.1, AL355816.2, DENND2D, CHI3L2, CHIAP1, CHIAP2, CHIA, AL356387.1, AL356387.2, PIFO, CHIAP3, HIGD1AP12, PGBP, OVGP1, AL390195.2, UBE2FP3, AL390195.1, WDR77, Y_RNA, ATP5PB, C1orf162, TMIGD3, RNU6-792P, ADORA3, RAP1A, LINC01160, KRT18P57, RNU6-151P, INKA2, INKA2-AS1, AL049557.1, DDX20.
- chr1:248,649,838–248,919,946, 15 genes, copy number 11: OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:97,492,663–99,322,741, 34 genes, copy number 10 (within-gene range 5–10): ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30.
- chr2:170,178,145–175,463,180, 99 genes, copy number 10–12 (broad region; genes not listed).
- chr2:175,923,882–180,939,298, 105 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr2:184,049,467–195,026,370, 120 genes, copy number 9–13 (broad region; genes not listed).
- chr2:197,693,106–197,774,823, 1 gene, copy number 10 (within-gene range 8–10): AC011997.1.
- chr2:197,726,879–199,471,266, 11 genes, copy number 10 (within-gene range 8–10): BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1.
- chr4:5,897,373–6,200,555, 1 gene, copy number 9 (within-gene range 6–9): C4orf50.
- chr4:6,026,199–13,051,411, 162 genes, copy number 9–24 (broad region; genes not listed).
- chr4:20,037,560–21,948,772, 9 genes, copy number 24 (within-gene range 3–24): AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978.
- chr4:24,998,847–27,282,225, 38 genes, copy number 21: LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3.
- chr8:59,455,885–59,893,942, 7 genes, copy number 10: RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1.
- chr8:60,876,969–62,249,879, 21 genes, copy number 10: AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1.
- chr8:124,141,888–135,742,495, 168 genes, copy number 9–12 (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 9: AC103955.1.
- chr8:142,834,247–142,916,506, 1 gene, copy number 14 (within-gene range 7–14): GML.
- chr8:142,872,356–144,108,124, 74 genes, copy number 14 (broad region; genes not listed).
- chr10:38,783,004–42,645,542, 19 genes, copy number 12: AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4.
- chr13:23,954,493–24,337,121, 12 genes, copy number 11: AL445985.2, AL359736.1, SPATA13, AL445985.1, IPO7P2, MIR2276, SPATA13-AS1, C1QTNF9, C1QTNF9-AS1, AL359736.2, NUS1P3, LINC00566.
- chr17:34,479,272–34,859,046, 6 genes, copy number 9: AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:73,334,384–75,708,062, 92 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr19:29,205,320–32,869,767, 70 genes, copy number 19–31 (broad region; genes not listed).
- chr19:37,304,451–40,629,818, 169 genes, copy number 23 (broad region; genes not listed).
- chr19:50,415,799–52,597,345, 166 genes, copy number 9–12 (broad region; genes not listed).
- chr19:52,597,699–52,598,887, 1 gene, copy number 9: AC022150.2.
- chr20:157,454–189,711, 2 genes, copy number 11 (within-gene range 6–11): DEFB127, DEFB128.

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
